CCDI case PBCEWI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ad379b81-3d09-488c-ac3a-952ed9429b25

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.8 years (293 days).

Biospecimens (2 samples)
- Sample 0DQC23: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQC27: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
